Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QG, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QG-01C (Primary Tumor).

[page 1 of 4]
Gender: Female	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:]	Final Results
--------------------------------	---------------

Surgical Pathology CASE NUMBER: DIAGNOSIS:	Final
--	-------

1. Liver, segment 2-3 hepatectomy (1FS): Telangiectatic adenoma with changes of steatohepatitis; Adjacent liver shows steatohepatitis with moderate steatosis, prominent ballooning injury, numerous Mallory bodies, moderate inflammation, and bridging fibrosis, see Note.
2. Liver, segment 4-5 resection, wedge biopsy: Telangiectatic adenoma with changes of steatohepatitis; Adjacent liver shows steatohepatitis with moderate steatosis, prominent ballooning injury, numerous Mallory bodies, moderate inflammation, and bridging fibrosis, see Note.
3. Adrenal gland, left, resection: Macro and micronodular hyperplasia.
4. Fat, left perinephric, resection: Fibroadipose tissue, no tumor seen.
5. Kidney, mass, resection: Renal cell carcinoma, chromophobe type, margins of resection are free of tumor.
6. Lymph node, preaortic, resection: Reactive lymph nodes, no tumor seen (0/10).
7. Lymph node, intraaortic caval, resection: Reactive lymph nodes, no tumor seen (0/10).
8. Lymph node, periaortic, resection: Reactive lymph nodes, no tumor seen (0/16).

ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site @ Kidney NOS
064.9
Jt 9/24/13

NOTE: Sections from specimen #1 and specimen #2 through the nodules in both wedge sections show a proliferation of hepatocytes with irregular fibrous septa and hemangioma-like collections of blood vessels. The lesion is partly encapsulated. Many normal arteries are present. The hepatocyte plates are 1-2 cells thick as demonstrated by reticulin stain in specimen #1 but not encapsulated in specimen #2. There is no ductular reaction. No mitotic activity is seen. Changes of steatohepatitis are present including steatosis, ballooning injury, and Mallory bodies. is positive in sinusoidal endothelial cells in the tumor. CK7 and CK19 are positive in scattered small cells probably representing hepatic stem cells. The liver adjacent to the nodule shows hepatic architecture distorted by the bridging fibrosis and early regenerative nodule formation. There is moderate macrovesicular steatosis. This is associated with prominent ballooning hepatocellular injury in zone 3 and frequent foci of lobular inflammation. There is mild portal chronic inflammation associated with mild focal interface hepatitis. Numerous Mallory bodies are seen as highlighted by ubiquitin immunostaining. The iron stain is positive in reticuloendothelial cells. The copper stain is negative. This patient has an advanced liver disease and is at risk for developing cirrhosis.

[page 2 of 4]
Gender: Female		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology (OrderID:	Final Results
------------------------------	---------------

Specimen #1 and #2 are evaluated by

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History: renal
mass, liver mass Specimen Taken For Protocol:

PROCEDURE: Pre-Operative Diagnosis: renal mass, liver mass
Post-Operative
Diagnosis: renal mass, liver mass Operative Findings:
renal mass,
liver mass

SPECIMENS SUBMITTED: 1. LIVER, Segment 2-3 hepatectomy (1FS)
2. LIVER WEDGE BIOPSY, Segment 4-5 resection
3. ADRENAL GLAND, LEFT, Left
4. FAT, Left perinephric
5. LIVER WEDGE BIOPSY, Renal mass
6. LYMPH NODES, Pre-aortic
7. LYMPH NODES, Intra-aortic caval
8. LYMPH NODES, Para - aortic

INTRAOPERATIVE CONSULTATION:

1FS "Segment 2 and 3 hepatectomy":
1FS diagnosis: Benign hepatocellular nodule.

GROSS DESCRIPTION: Received are 8 formalin-filled containers labeled with the patient's name, medical record number, and further specified as follows:

1. "Segment 2 and 3 hepatectomy", consists of a red-tan tissue measuring 14 x 8 x 3 cm. Approximately 0.6 x 0.3 x 0.1 from tumor area is frozen as 1FS. In Surgical Pathology, the frozen tissue is transferred to an orange cassette labeled FS and the liver is inked in black on the upper surface and yellow on the bottom surface, blue in the staple resection margin. There is a nodule measuring 1.7 x 1.1 x 2.2 cm. Representative sections are submitted in white cassettes labeled A-1G (representative staple sections in 1A-1C; The tumor nodule in 1D-1F; The normal hepatic parenchyma in 1G) for permanent processing. Approximately 3 x 2 x 0.4 cm of tissue is procured for Additional sections from the tumor are submitted in white cassettes +1M for permanent processing.

[page 3 of 4]
Gender: Female	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:**Final Results**

2. "Segment 4 and 5 wedge resection", consists of a tan-brown liver tissue measuring 8 x 3 x 2 cm. The specimen is serially sectioned. No gross lesion is noted. The surgical resection margin is inked in blue and four representative sections are submitted in white cassettes labeled for permanent processing.
3. "Left adrenal". The specimen is an adrenal gland with fat, weighing 53.2 grams, measuring 7 x 2.5 x 3 cm. The fat measures 9 x 5 x 1 cm. The specimen is inked black and then bisected revealing a yellow nodule measuring up to 0.5 x 0.5 x 0.4 cm. The nodule is procured for In Surgical Pathology, the specimen received matches the above description and representative sections of the adrenal are submitted in 3A-3C for the adrenal tumor, and 3D-3E for fatty tissue margins.
4. "Left perinephric fat", consists of a specimen of adipose tissue measuring 18 x 9 x 4.5 cm. No lymph nodes were noted in the gross examination. Three representative sections are submitted in white cassettes labeled for permanent processing.
5. "Left renal mass", consists of a tan soft tissue measuring 5 x 4.5 x 3.5 cm. The staple section is inked in red and the capsule was inked in blue. The pelvis and artery and veins from the surgical section margin is submitted in white cassette There is a nodule measuring 1.7 x 1.5 x 1.2 noted in the cut surface. The nodule is close to the capsule and representative tumor is submitted in white cassettes 5B-5E, and the normal kidney parenchyma is submitted in white cassettes labeled for permanent processing.
6. "Preaortic lymph node", consists of a piece of lymphoid adipose tissue measuring 5 x 2.5 x 1 cm. There are 6 lymph nodes measuring up to 0.8 cm in greatest dimension. They are submitted in white cassettes labeled for permanent processing.
7. "Intra-aortic lymph node", consists of a piece of adipose tissue measuring 3.5x1.8x1cm. There are multiple lymph nodes measuring up to 0.7cm in the greatest dimension. They are serially sectioned and entirely submitted in white cassettes labeled for permanent processing.
8. "Para-aortic lymph node", consists of adipose tissue measuring 8 x 3 x 2.5 cm. There are multiple lymph nodes in the specimen. They are submitted in white cassettes labeled 3A-8D for permanent processing.
The procurements were done by
Gross description dictated by

[page 4 of 4]
Gender: Female	Birth Date:	Admit Protocol
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology (OrderID:	Final Results
------------------------------	---------------

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file fb42b543-1ed3-4ade-894d-98fda560b35a (TCGA-KM-A7QG.47DE599A-EEED-4A9E-B1C2-9F63598A9C4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).